Surgical pathology report (de-identified scan), TCGA case TCGA-S9-A6TU, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Dept of Neurosurgery at University of Heidelberg, specimen TCGA-S9-A6TU-01A (Primary Tumor).

Histomorphology typical for diffuse astrocytoma. Proliferation index 2%.
Borderline case with increased nuclear pleomorphism.

Diagnosis

Astrocytoma WHO grade II

CLF ICD-O-3
Astrocytoma, grade II 9400/3
path
Astrocytoma, diffuse 9400/3
Site: Brain, supratentorial NOS C71.0
7/25/13

Untranslated original report
is housed at the BCR

Source: NCI Genomic Data Commons file d28daabd-b1d0-461d-857e-1812149c1827 (TCGA-S9-A6TU.8CD1578E-88C2-4328-97B8-C3DD437C15A1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).